Somatic mutation profile of tumor specimen TCGA-06-2559-01A (aliquot TCGA-06-2559-01A-01W-0837-08) from TCGA case TCGA-06-2559, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 83.7 years (30,580 days).
Specimen TCGA-06-2559-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4de091e4-63a6-4848-b80f-827ab6e5b4d2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-06-2559-10A (Blood Derived Normal), aliquot TCGA-06-2559-10A-01D-1494-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dc8ff953-cc9f-4971-adcd-4836e8d492bc

The open-access MAF lists 64 somatic variants for this specimen: 46 protein-altering or splice-affecting, 17 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 41, Silent 17, Splice Region 1, Splice Site 1, Frame Shift Del 1, Frame Shift Ins 1, 3'Flank 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- B4GALNT1 | c.263dup p.L89Pfs*13 | Frame Shift Ins (INS) | VAF 34/210 reads (16%) | catalogued as rs745744124; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- PTEN | c.477G>T p.R159S | Missense Mutation (SNP) | VAF 59/89 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1057519724, COSV64288957, COSV64298985; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.569C>T p.P190L | Missense Mutation (SNP) | VAF 81/171 reads (47%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen possibly damaging (0.467); catalogued as rs876660825, CM161004, COSV52664064, COSV52987047, COSV53313892; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TP53 | c.464C>A p.T155N | Missense Mutation (SNP) | VAF 112/252 reads (44%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.666); catalogued as rs786202752, CM942117, HM090066, COSV52692291, COSV52711720, COSV52741190, COSV52782333; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- BCOR | c.3653G>A p.W1218* (on ENST00000378444 / NM_001123385.2; = p.W1184* on NM_017745.6) | Nonsense Mutation (SNP) | VAF 59/70 reads (84%) | catalogued as COSV60705485; called by muse, mutect2, varscan2
- CARMIL3 | c.605G>A p.R202Q | Missense Mutation (SNP) | VAF 25/195 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as rs182632230, COSV57728051; called by muse, mutect2, varscan2
- CHD8 | c.2671G>C p.G891R (on ENST00000646647 / NM_001170629.2; = p.G612R on NM_020920.4) | Missense Mutation (SNP) | VAF 92/289 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67872338; called by muse, mutect2, varscan2
- COL17A1 | c.2981C>T p.P994L | Missense Mutation (SNP) | VAF 103/126 reads (82%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as rs763518143, COSV62227033, COSV62229351; called by muse, mutect2, varscan2
- CTHRC1 | c.436C>T p.R146W | Missense Mutation (SNP) | VAF 27/551 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs747888820, COSV57716227; called by muse, mutect2
- GRM8 | c.2030T>C p.F677S | Missense Mutation (SNP) | VAF 96/369 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58860088; called by muse, mutect2, varscan2
- IL18RAP | c.796+1G>T p.X266_splice | Splice Site (SNP) | VAF 69/176 reads (39%) | catalogued as COSV51824366, COSV51828651; called by muse, mutect2, varscan2
- KCTD19 | c.2302G>A p.V768M | Missense Mutation (SNP) | VAF 54/160 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.336); catalogued as rs773175029, COSV58574635; called by mutect2, varscan2
- KIR2DL4 | c.232G>A p.A78T (on ENST00000396284; = p.A39T on NM_001080770.2) | Missense Mutation (SNP) | VAF 219/653 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.035); catalogued as rs369994438, COSV60877402; called by muse, mutect2, varscan2
- KRCC1 | c.601G>A p.E201K | Missense Mutation (SNP) | VAF 13/296 reads (4%) | SIFT tolerated (0.43); PolyPhen benign (0.024); catalogued as COSV61252138; called by muse, mutect2
- LRP2 | c.12389T>C p.L4130P | Missense Mutation (SNP) | VAF 236/569 reads (41%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV55569927; called by muse, mutect2, varscan2
- LTBP1 | c.1032G>A p.Q344= | Splice Region (SNP) | VAF 185/421 reads (44%) | catalogued as COSV63196148; called by muse, mutect2, varscan2
- MAP3K1 | c.1462T>C p.C488R | Missense Mutation (SNP) | VAF 106/229 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV68126715; called by muse, mutect2, varscan2
- MAPK1 | c.730C>T p.L244F | Missense Mutation (SNP) | VAF 37/92 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV53185206, COSV53188915; called by muse, mutect2, varscan2
- MOCS1 | c.277G>A p.V93I | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.633); catalogued as rs1314629193, COSV57940023; called by muse, mutect2, varscan2
- NEUROG2 | c.375G>A p.M125I | Missense Mutation (SNP) | VAF 74/196 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV57637951; called by muse, mutect2, varscan2
- NEXN | c.562A>T p.N188Y | Missense Mutation (SNP) | VAF 7/83 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.653); catalogued as COSV53944319; called by muse, mutect2
- NLRC5 | c.3518C>T p.T1173M | Missense Mutation (SNP) | VAF 75/1316 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.075); catalogued as rs952638793, COSV52652607; called by muse, mutect2
- NLRP4 | c.763C>T p.R255W | Missense Mutation (SNP) | VAF 108/238 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs756196545, COSV56712737, COSV56721500; called by muse, mutect2, varscan2
- NPAP1 | c.155G>A p.R52H | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as rs755681616, COSV100274534, COSV61510472; called by muse, mutect2, varscan2
- ODF4 | c.181C>T p.R61C | Missense Mutation (SNP) | VAF 46/119 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as rs147153349, COSV60272108; called by muse, mutect2, varscan2
- OR10S1 | c.913C>T p.R305W | Missense Mutation (SNP) | VAF 78/304 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs771347462, COSV73342706; called by muse, mutect2, varscan2
- OR7A17 | c.244C>T p.L82F | Missense Mutation (SNP) | VAF 33/398 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs964223126, COSV59414366; called by muse, mutect2
- PCDH11X | c.1553G>A p.R518H | Missense Mutation (SNP) | VAF 39/41 reads (95%) | SIFT tolerated (0.14); PolyPhen benign (0.231); catalogued as rs772498943, COSV53497403; called by muse, mutect2, varscan2
- PDGFRA | c.1114G>A p.E372K | Missense Mutation (SNP) | VAF 634/2796 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as COSV57272637; called by muse, mutect2, varscan2
- PDGFRA | c.1965G>C p.L655F | Missense Mutation (SNP) | VAF 410/3022 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57272642, COSV99957332; called by muse, mutect2, varscan2
- PRDM9 | c.1760G>A p.R587Q | Missense Mutation (SNP) | VAF 126/362 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.235); catalogued as COSV57011927; called by muse, mutect2, varscan2
- PSG5 | c.725C>T p.P242L | Missense Mutation (SNP) | VAF 297/707 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.221); catalogued as COSV61654835; called by muse, mutect2, varscan2
- PTPRS | c.3359A>G p.N1120S | Missense Mutation (SNP) | VAF 40/90 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as rs372506721, COSV53634249; called by muse, mutect2, varscan2
- SCNN1G | c.1593C>A p.F531L | Missense Mutation (SNP) | VAF 86/169 reads (51%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV55597975, COSV55601439; called by muse, mutect2, varscan2
- SLC25A16 | c.850C>T p.R284W | Missense Mutation (SNP) | VAF 158/275 reads (57%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs763985940, COSV56263782; called by muse, mutect2, varscan2
- SMG8 | c.2056A>G p.T686A | Missense Mutation (SNP) | VAF 70/222 reads (32%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.983); catalogued as COSV56286740; called by muse, mutect2, varscan2
- SPTA1 | c.196G>A p.G66R | Missense Mutation (SNP) | VAF 54/119 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.295); catalogued as COSV63758056; called by muse, mutect2, varscan2
- TAF1L | c.4999G>A p.D1667N | Missense Mutation (SNP) | VAF 285/765 reads (37%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.103); catalogued as COSV54267636; called by muse, mutect2, varscan2
- TAF6 | c.1399C>T p.R467W | Missense Mutation (SNP) | VAF 34/143 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.924); catalogued as COSV59843257; called by muse, mutect2, varscan2
- TMF1 | c.2765A>G p.K922R | Missense Mutation (SNP) | VAF 6/138 reads (4%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV68375617; called by muse, mutect2
- TMPPE | c.1298G>T p.G433V | Missense Mutation (SNP) | VAF 62/132 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56567324; called by muse, mutect2, varscan2
- XIRP2 | c.8498T>A p.V2833E (on ENST00000628543; = p.V3008E on NM_152381.6) | Missense Mutation (SNP) | VAF 8/175 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.276); catalogued as COSV99738771; called by muse, mutect2
- PDGFRL | c.670G>A p.V224I | Missense Mutation (SNP) | VAF 31/434 reads (7%) | SIFT tolerated (0.52); PolyPhen benign (0); called by muse, mutect2
- TECPR2 | c.2081G>T p.S694I | Missense Mutation (SNP) | VAF 7/121 reads (6%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.143); called by muse, mutect2
- TG | c.7065del p.L2356Cfs*8 | Frame Shift Del (DEL) | VAF 46/138 reads (33%) | called by mutect2, pindel, varscan2
- ZNF658 | c.2874A>T p.R958S | Missense Mutation (SNP) | VAF 125/290 reads (43%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- ADAMTS14 | c.1467C>T p.G489= | Silent (SNP) | VAF 34/38 reads (89%) | catalogued as COSV64605633; called by muse, mutect2, varscan2
- ADGRV1 | c.7153C>T p.L2385= | Silent (SNP) | VAF 22/42 reads (52%) | catalogued as COSV67993636; called by muse, varscan2
- ANKRD30A | c.3171G>A p.E1057= (on ENST00000611781; = p.E1001= on NM_052997.2) | Silent (SNP) | VAF 23/55 reads (42%) | catalogued as COSV64618769; called by muse, mutect2, varscan2
- CPN2 | c.753C>T p.N251= | Silent (SNP) | VAF 11/51 reads (22%) | catalogued as rs753849442, COSV60469685; called by muse, mutect2, varscan2
- DHRS2 | c.339C>T p.G113= | Silent (SNP) | VAF 64/153 reads (42%) | catalogued as rs1393894434, COSV51631007; called by muse, mutect2, varscan2
- EEF1AKMT1 | c.102C>T p.G34= | Silent (SNP) | VAF 51/247 reads (21%) | catalogued as rs558722857, COSV66964467; called by muse, mutect2, varscan2
- FBN2 | c.1452C>A p.I484= | Silent (SNP) | VAF 91/223 reads (41%) | catalogued as COSV52539762, COSV99330231; called by muse, mutect2, varscan2
- HRNR | c.1269T>C p.S423= | Silent (SNP) | VAF 12/51 reads (24%) | catalogued as COSV64262019; called by muse, mutect2
- ITGAD | c.387G>A p.S129= | Silent (SNP) | VAF 35/72 reads (49%) | catalogued as rs750617929, COSV66757365; called by muse, mutect2, varscan2
- KRT27 | c.708G>A p.A236= | Silent (SNP) | VAF 92/188 reads (49%) | catalogued as COSV56971978, COSV56973101; called by muse, varscan2
- LRP2 | c.3213G>A p.A1071= | Silent (SNP) | VAF 37/466 reads (8%) | catalogued as rs530329919, COSV55569939; called by muse, mutect2
- MYH13 | c.4671C>T p.H1557= | Silent (SNP) | VAF 28/49 reads (57%) | catalogued as rs764908477, COSV52840110; called by muse, mutect2, varscan2
- NMBR | c.300C>T p.D100= | Silent (SNP) | VAF 7/105 reads (7%) | catalogued as COSV57800315; called by muse, mutect2
- OTOA | c.483C>T p.L161= | Silent (SNP) | VAF 136/327 reads (42%) | catalogued as rs756856872, COSV53762469; called by muse, mutect2, varscan2
- PCDHGB4 | c.1518C>T p.S506= | Silent (SNP) | VAF 49/115 reads (43%) | catalogued as COSV54014637; called by muse, mutect2, varscan2
- SEPTIN4 | c.729G>T p.L243= | Silent (SNP) | VAF 30/188 reads (16%) | catalogued as COSV57898977; called by muse, mutect2, varscan2
- UHRF1BP1 | c.3132G>A p.V1044= | Silent (SNP) | VAF 149/352 reads (42%) | catalogued as COSV51956593, COSV51959480; called by muse, mutect2, varscan2
- AC092718.9 | chr16:81154092 G>C | 3'Flank (SNP) | VAF 9/19 reads (47%) | catalogued as rs1488177262; called by muse, mutect2, varscan2
